Somatic mutation profile of tumor specimen C3L-02216-01 (aliquot CPT0104690009) from CPTAC case C3L-02216, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage III; Tumor grade: G1; Age at diagnosis: 68.7 years (25,087 days).
Specimen C3L-02216-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 710ba45a-1d4c-442c-bf98-21fa5b6f38e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02216-31 (Blood Derived Normal), aliquot CPT0105150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76643a4b-299d-41bf-9c7a-e1f8a5a9cb21

The open-access MAF lists 1,094 somatic variants for this specimen: 735 protein-altering or splice-affecting, 200 silent, 159 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 498, Silent 200, Frame Shift Del 159, Intron 94, Frame Shift Ins 25, 3'UTR 23, Nonsense Mutation 21, RNA 17, Splice Site 14, Splice Region 10, 5'Flank 9, In Frame Del 8.

Variants (750 of 1,094; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 143/358 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 58/162 reads (36%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- COL5A1 | c.2988del p.G997Afs*77 | Frame Shift Del (DEL) | VAF 122/342 reads (36%) | catalogued as rs764693725; ClinVar: pathogenic; called by mutect2, varscan2
- CRYGD | c.475del p.A159Pfs*9 | Frame Shift Del (DEL) | VAF 47/160 reads (29%) | catalogued as rs764945940; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- DYNC1H1 | c.9684G>C p.E3228D | Missense Mutation (SNP) | VAF 67/495 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); catalogued as rs1555411143; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- F8 | c.209_212del p.F70* | Frame Shift Del (DEL) | VAF 93/292 reads (32%) | catalogued as rs387906434; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GAA | c.2242del p.E748Rfs*16 | Frame Shift Del (DEL) | VAF 108/303 reads (36%) | catalogued as rs777275355, CM082763, CM128388, CM970554; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 44/155 reads (28%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 78/210 reads (37%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 100/344 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- NOTCH1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 11/330 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1057523819, COSV53030190; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 17/47 reads (36%) | hotspot (GDC flag); called by pindel, varscan2
- PTEN | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 89/299 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1111457, COSV64291669, COSV64295080, COSV64295612; called by muse, mutect2, varscan2
- PTEN | c.492+2T>G p.X164_splice | Splice Site (SNP) | VAF 68/188 reads (36%) | catalogued as rs1554898244, CD115958, CS982333, COSV64288576, COSV64288590; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SOS1 | c.797C>A p.T266K | Missense Mutation (SNP) | VAF 134/388 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs137852812, CM070270; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3740C>T p.T1247I (on ENST00000272895 / NM_173076.3; = p.T929I on NM_015657.3) | Missense Mutation (SNP) | VAF 36/359 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV55950378; called by muse, mutect2, varscan2
- ACHE | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 91/243 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1284197647; called by muse, mutect2, varscan2
- ACSBG1 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.097); catalogued as rs1188043232; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM11 | c.1397G>A p.C466Y | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52347715; called by muse, mutect2, varscan2
- ADAM19 | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 109/276 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57424132, COSV99977381; called by muse, mutect2, varscan2
- ADCY6 | c.1684_1686del p.E562del | In Frame Del (DEL) | VAF 22/172 reads (13%) | catalogued as rs1392097953; called by pindel, varscan2
- ADCY8 | c.3500C>T p.T1167M | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356343883, COSV53897190; called by muse, mutect2, varscan2
- ADGRG4 | c.8874del p.F2958Lfs*6 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | catalogued as rs771931957; called by mutect2, pindel
- ADNP2 | c.1972G>A p.G658S | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs572333470, COSV51542219; called by muse, mutect2, varscan2
- ADSS1 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs779075124; called by muse, mutect2, varscan2
- AFTPH | c.2410G>A p.V804I | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as rs760298221, COSV53217793; called by muse, mutect2, varscan2
- AGAP6 | c.1480C>T p.R494* (on ENST00000374056 / NM_001365867.1; = p.R517* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 87/701 reads (12%) | catalogued as rs782767193, COSV65017686; called by muse, mutect2, varscan2
- AHDC1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.182); catalogued as rs761143012; called by muse, mutect2, varscan2
- AMFR | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1308746346; called by muse, mutect2, varscan2
- ANKMY1 | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99802530; called by muse, mutect2, varscan2
- ANKRD24 | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 100/254 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.284); catalogued as rs200312560; called by muse, mutect2, varscan2
- ANKRD62 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 101/301 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.072); catalogued as rs1399136447, COSV58412212; called by muse, mutect2, varscan2
- ANO4 | c.1328A>T p.E443V (on ENST00000392977 / NM_001286615.2; = p.E408V on NM_178826.4) | Missense Mutation (SNP) | VAF 80/234 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV54595532; called by muse, mutect2, varscan2
- APC | c.1875G>C p.Q625H | Missense Mutation (SNP) | VAF 57/444 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as CD930888, COSV57376890; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 72/198 reads (36%) | catalogued as rs773922861; called by mutect2, varscan2
- ARHGAP22 | c.2035_2037del p.E679del | In Frame Del (DEL) | VAF 65/276 reads (24%) | catalogued as rs1397383980; called by pindel, varscan2
- ARHGAP39 | c.1095dup p.S366Lfs*90 | Frame Shift Ins (INS) | VAF 28/84 reads (33%) | catalogued as rs751388541; called by mutect2, varscan2
- ARHGAP5 | c.3230T>C p.V1077A | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766156861; called by muse, mutect2, varscan2
- ARHGEF12 | c.3347C>T p.T1116I | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs374162884; called by muse, mutect2, varscan2
- ARHGEF19 | c.403_405del p.K135del | In Frame Del (DEL) | VAF 42/119 reads (35%) | catalogued as rs756719819; called by pindel, varscan2
- ARPC5 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as COSV54172374; called by muse, mutect2, varscan2
- ARSJ | c.1736dup p.K580Efs*32 | Frame Shift Ins (INS) | VAF 47/160 reads (29%) | catalogued as rs753865255; called by mutect2, varscan2
- ASB9 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as rs1473100858, COSV66851236; called by muse, mutect2
- ASF1B | c.302A>G p.Y101C | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764860053; called by muse, mutect2, varscan2
- ASPG | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs571949398; called by muse, mutect2, varscan2
- ASPHD2 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); catalogued as rs763510073; called by muse, mutect2
- ASTN1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.989); catalogued as rs533960916, COSV56065847; called by muse, mutect2, varscan2
- ATP2B3 | c.3329G>A p.R1110Q | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782643695, COSV99686204; called by muse, mutect2, varscan2
- ATP9B | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); catalogued as COSV56946532; called by muse, mutect2, varscan2
- AXIN1 | c.1736C>T p.S579L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1246759263; called by muse, mutect2
- BAZ2A | c.5317G>A p.A1773T | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV51642161; called by muse, mutect2, varscan2
- BCAR3 | c.2435C>T p.S812L | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369490013; called by muse, mutect2, varscan2
- BEST4 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs140513742; called by muse, mutect2, varscan2
- BEX4 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs747374478, COSV101015435; called by muse, mutect2, varscan2
- BICRA | c.2935del p.A979Pfs*67 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs756990560, COSV67605323; called by mutect2, pindel, varscan2
- BOP1 | c.1303G>T p.G435C | Missense Mutation (SNP) | VAF 124/342 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.317); catalogued as rs933163282; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- C1QTNF5 | c.552del p.W185Gfs*13 | Frame Shift Del (DEL) | VAF 50/174 reads (29%) | catalogued as rs776247392; called by pindel, varscan2
- C4orf50 | c.331G>A p.E111K (on ENST00000324058; = p.E1343K on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs1288076910, COSV100136175; called by muse, mutect2, varscan2
- C5 | c.1996+1G>A p.X666_splice | Splice Site (SNP) | VAF 83/254 reads (33%) | catalogued as rs753313016; called by muse, mutect2, varscan2
- C7orf33 | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as rs765216372; called by muse, mutect2, varscan2
- C8orf89 | c.457del p.S153Afs*16 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs951061763; called by mutect2, varscan2
- CATSPER1 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs765046118, COSV100375926; called by muse, mutect2, varscan2
- CC2D1A | c.2693del p.G898Vfs*45 | Frame Shift Del (DEL) | VAF 40/128 reads (31%) | catalogued as rs1423002835; called by mutect2, pindel, varscan2
- CCDC184 | c.190del p.A64Pfs*30 | Frame Shift Del (DEL) | VAF 64/178 reads (36%) | catalogued as rs750406248; called by mutect2, pindel, varscan2
- CD14 | c.4-1G>T p.X2_splice | Splice Site (SNP) | VAF 66/153 reads (43%) | catalogued as COSV100117449; called by muse, mutect2, varscan2
- CD276 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs770116040, COSV59204254; called by muse, mutect2, varscan2
- CD82 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs574662941, COSV57034164, COSV99907558; called by muse, mutect2, varscan2
- CDAN1 | c.3301G>A p.A1101T | Missense Mutation (SNP) | VAF 86/257 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV51910189; called by muse, mutect2, varscan2
- CDCA2 | c.2986C>T p.R996W | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs373278295; called by muse, mutect2, varscan2
- CDH16 | c.1686del p.K563Sfs*22 | Frame Shift Del (DEL) | VAF 57/166 reads (34%) | catalogued as rs776664434; called by mutect2, pindel, varscan2
- CEP128 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.242); catalogued as rs779458155, COSV53673343; called by muse, mutect2
- CEP76 | c.1055_1056del p.P352Rfs*7 | Frame Shift Del (DEL) | VAF 64/206 reads (31%) | catalogued as rs747411650; called by mutect2, pindel, varscan2
- CERCAM | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs142520790; called by muse, mutect2, varscan2
- CKAP2L | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs750251080, COSV56695605; called by muse, mutect2, varscan2
- CKLF | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV99862606; called by muse, mutect2
- CNBD2 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs539557197, COSV62588051; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 60/140 reads (43%) | catalogued as rs374805044; called by mutect2, varscan2
- COX20 | c.149del p.L50Cfs*14 | Frame Shift Del (DEL) | VAF 53/173 reads (31%) | catalogued as rs1313693363; called by pindel, varscan2
- CRB3 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769244816, COSV57568331; called by muse, mutect2, varscan2
- CSMD2 | c.5771G>A p.R1924H | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201751199; called by muse, mutect2, varscan2
- CSMD3 | c.9136C>T p.P3046S (on ENST00000297405 / NM_001363185.1; = p.P2877S on NM_052900.3) | Missense Mutation (SNP) | VAF 86/258 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52271263; called by muse, mutect2, varscan2
- CTBP2 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as rs76390727; called by muse, mutect2, varscan2
- CUL7 | c.1646A>G p.Q549R | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99538071; called by muse, mutect2, varscan2
- CYBA | c.467del p.P156Rfs*35 | Frame Shift Del (DEL) | VAF 54/183 reads (30%) | catalogued as CM910096; called by pindel, varscan2
- DBH | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV55041784; called by muse, mutect2, varscan2
- DDX21 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); catalogued as rs200756197, COSV62555017; called by muse, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs772416332; called by mutect2, varscan2
- DHX37 | c.3305C>T p.T1102M | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs146941853; called by muse, mutect2
- DIPK1B | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.91); catalogued as rs572899469; called by muse, mutect2, varscan2
- DLEC1 | c.1425dup p.V476Rfs*58 | Frame Shift Ins (INS) | VAF 32/102 reads (31%) | catalogued as rs756971918; called by mutect2, pindel, varscan2
- DMP1 | c.797A>T p.K266I | Missense Mutation (SNP) | VAF 42/502 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56819760; called by muse, mutect2
- DNAH1 | c.2806_2808del p.E936del | In Frame Del (DEL) | VAF 44/166 reads (27%) | catalogued as rs760244561; called by pindel, varscan2
- DNAH10 | c.7824del p.G2609Afs*10 (on ENST00000409039; = p.G2548Afs*10 on NM_207437.3) | Frame Shift Del (DEL) | VAF 78/240 reads (33%) | catalogued as rs1266428236, COSV68987896; called by mutect2, varscan2
- DNAH10 | c.8578G>A p.A2860T (on ENST00000409039; = p.A2799T on NM_207437.3) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs751930117; called by muse, mutect2, varscan2
- DOCK8 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 110/395 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.045); catalogued as rs769150252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOK7 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs767804171; called by muse, mutect2, varscan2
- DRD4 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as rs1411413998; called by muse, mutect2, varscan2
- DUS3L | c.1908dup p.S637Qfs*? | Frame Shift Ins (INS) | VAF 52/172 reads (30%) | catalogued as rs1232406748; called by mutect2, pindel, varscan2
- DYSF | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 77/343 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs886043941, COSV50325367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EBF3 | c.827C>T p.T276M (on ENST00000355311 / NM_001375392.1; = p.T267M on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV62475831, COSV62478533; called by muse, mutect2, varscan2
- EFCC1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs1391726185; called by muse, mutect2, varscan2
- EGFLAM | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.061); catalogued as rs1051511388, COSV100471510; called by muse, mutect2, varscan2
- EIF2D | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs150459038; called by muse, mutect2, varscan2
- ELAC2 | c.433-1G>C p.X145_splice | Splice Site (SNP) | VAF 15/273 reads (5%) | catalogued as COSV100568349; called by muse, mutect2
- ELMO3 | c.800A>G p.D267G (on ENST00000652269; = p.D214G on NM_024712.5) | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.202); catalogued as rs1299202998; called by muse, mutect2, varscan2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs761717176; called by mutect2, varscan2
- ENTPD6 | c.1242C>T p.Y414= | Splice Region (SNP) | VAF 18/72 reads (25%) | catalogued as rs777107194, COSV61751500; called by muse, mutect2, varscan2
- ENTPD7 | c.753_755del p.R252del | In Frame Del (DEL) | VAF 46/144 reads (32%) | catalogued as rs1418033504; called by pindel, varscan2
- EPG5 | c.6584C>T p.A2195V | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs764699240, COSV56348446; called by muse, mutect2, varscan2
- EPHB4 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs112443300, COSV62268318; called by muse, mutect2, varscan2
- EPHB6 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 110/344 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs1563346311; called by muse, mutect2, varscan2
- EPM2AIP1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs753022345; called by muse, mutect2, varscan2
- EPS15L1 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs369307683; called by muse, mutect2, varscan2
- ERF | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55895555, COSV55896256; called by muse, mutect2, varscan2
- ERGIC2 | c.25del p.T9Lfs*2 | Frame Shift Del (DEL) | VAF 17/141 reads (12%) | catalogued as rs1370236096; called by mutect2, pindel, varscan2
- ESRP1 | c.28_30del p.V10del | In Frame Del (DEL) | VAF 26/139 reads (19%) | catalogued as rs756027861; called by pindel, varscan2
- ESRP1 | c.1280del p.P427Lfs*55 | Frame Shift Del (DEL) | VAF 32/150 reads (21%) | catalogued as COSV64412044; called by mutect2, pindel, varscan2
- ESYT3 | c.1500_1503del p.S500Rfs*29 | Frame Shift Del (DEL) | VAF 35/118 reads (30%) | catalogued as rs1398210964; called by mutect2, pindel, varscan2
- EVI2B | c.593dup p.N198Kfs*4 | Frame Shift Ins (INS) | VAF 65/192 reads (34%) | catalogued as rs765136869, COSV58364207; called by mutect2, varscan2
- EXT1 | c.15del p.K5Nfs*131 | Frame Shift Del (DEL) | VAF 110/314 reads (35%) | catalogued as rs759834555; called by mutect2, pindel, varscan2
- FAM160A2 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs777403512; called by muse, mutect2, varscan2
- FAS | c.403del p.C135Vfs*52 | Frame Shift Del (DEL) | VAF 102/409 reads (25%) | catalogued as rs1564692984, CX113055, COSV58238368; called by pindel, varscan2*
- FAT3 | c.4006C>T p.R1336C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1211966374; called by muse, mutect2, varscan2
- FBXL7 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746538228, COSV61650308, COSV61652729; called by muse, mutect2, varscan2
- FBXW5 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as rs776988341; called by muse, mutect2, varscan2
- FGF3 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 116/350 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782315409, COSV61926632, COSV61926765; called by muse, mutect2, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 38/135 reads (28%) | catalogued as COSV58769165; called by mutect2, varscan2
- FKBP6 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 145/402 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs373566157; called by muse, mutect2, varscan2
- FLCN | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 72/425 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1223326792; called by muse, mutect2, varscan2
- FLT1 | c.839G>C p.R280P | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV56731335; called by muse, mutect2, varscan2
- FOXRED1 | c.248A>G p.K83R | Missense Mutation (SNP) | VAF 46/452 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.631); catalogued as rs1405065321; called by muse, mutect2
- FRMPD1 | c.1739G>A p.S580N | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.073); catalogued as rs140481463; called by muse, mutect2, varscan2
- FRMPD3 | c.3039del p.S1014Afs*18 | Frame Shift Del (DEL) | VAF 58/194 reads (30%) | catalogued as rs752351689; called by mutect2, pindel, varscan2
- FSIP2 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs530395127; called by muse, mutect2, varscan2
- GAK | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs764527121, COSV58504623; called by muse, mutect2, varscan2
- GALNT10 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs142364912; called by muse, mutect2, varscan2
- GARRE1 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1397500540, COSV100209637, COSV55101086; called by muse, mutect2, varscan2
- GAS2L2 | c.588dup p.R197Qfs*34 | Frame Shift Ins (INS) | VAF 30/140 reads (21%) | catalogued as rs1555599547; called by pindel, varscan2
- GDF6 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.487); catalogued as COSV99748239; called by muse, mutect2, varscan2
- GJA8 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 88/266 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as rs782398342, COSV53788198; called by mutect2, varscan2
- GJB5 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs771357421, COSV58355381; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GPR4 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59918452; called by muse, mutect2, varscan2
- GPSM1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.897); catalogued as rs532206618; called by muse, mutect2, varscan2
- GRIN3A | c.1879A>G p.M627V | Missense Mutation (SNP) | VAF 160/430 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV62455447; called by muse, mutect2, varscan2
- GRIN3B | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1355130133, COSV52260907; called by muse, mutect2, varscan2
- GRM6 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as rs774644036, COSV51436399; called by muse, mutect2, varscan2
- GRM6 | c.727dup p.V243Gfs*40 | Frame Shift Ins (INS) | VAF 114/334 reads (34%) | catalogued as rs281865186; ClinVar: not provided; called by mutect2, varscan2
- GTF3C1 | c.5541del p.E1848Rfs*33 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs763161381; called by mutect2, pindel, varscan2
- H4C5 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV63487107; called by muse, mutect2, varscan2
- HDHD2 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1269969627, COSV100321398; called by muse, mutect2, varscan2
- HECW1 | c.4000G>A p.V1334I | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs761127676; called by muse, mutect2, varscan2
- HESX1 | c.533del p.N178Ifs*10 | Frame Shift Del (DEL) | VAF 54/140 reads (39%) | catalogued as rs759180706; called by mutect2, varscan2
- HEYL | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as rs773914888; called by muse, mutect2, varscan2
- HIRA | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs1157533113, COSV54281580; called by muse, mutect2
- HKDC1 | c.1513G>A p.G505R | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.067); catalogued as rs376743885; called by muse, mutect2, varscan2
- HMGN5 | c.663del p.E222Rfs*5 | Frame Shift Del (DEL) | VAF 56/194 reads (29%) | catalogued as rs923608724; called by mutect2, pindel, varscan2
- HNF1A | c.1136del p.P379Lfs*5 | Frame Shift Del (DEL) | VAF 60/190 reads (32%) | catalogued as COSV57466638; called by mutect2, varscan2
- HNRNPA2B1 | c.7-3del | Splice Region (DEL) | VAF 15/84 reads (18%) | catalogued as rs759915055; called by pindel, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs767148651; called by mutect2, varscan2
- HPS3 | c.685A>G p.N229D | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs201855201; called by muse, mutect2, varscan2
- IGSF21 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV52142040; called by muse, mutect2
- INSR | c.3808C>T p.R1270C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs371841833; called by muse, mutect2
- INSR | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 97/261 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs556950372, COSV57160009; called by muse, mutect2, varscan2
- IQCA1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs755009497, COSV54508915; called by muse, mutect2, varscan2
- IRX2 | c.969del p.A324Pfs*75 | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | catalogued as COSV57410141; called by mutect2, pindel, varscan2
- IRX2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1465414369; called by muse, mutect2, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 74/212 reads (35%) | catalogued as rs762230866, COSV99339624; called by mutect2, pindel, varscan2
- ITGA1 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs780856119; called by muse, mutect2, varscan2
- ITGB5 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 47/127 reads (37%) | catalogued as rs765273857; called by muse, mutect2, varscan2
- ITPR1 | c.4499C>T p.T1500M (on ENST00000354582; = p.T1485M on NM_002222.7) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370021605, COSV56969810; called by muse, mutect2, varscan2
- KATNIP | c.4486A>G p.T1496A | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1282669384; called by muse, mutect2, varscan2
- KDM3B | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1269846621; called by muse, mutect2, varscan2
- KDM4B | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as rs1168192294, COSV50257582; called by muse, mutect2, varscan2
- KIAA2012 | c.3131G>T p.R1044L | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT deleterious (0); catalogued as rs1016224737; called by muse, mutect2, varscan2
- KIF13A | c.3345dup p.V1116Sfs*4 | Frame Shift Ins (INS) | VAF 34/106 reads (32%) | catalogued as rs1346755993; called by mutect2, varscan2
- KIF2C | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283621357, COSV64765639; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 100/314 reads (32%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 29/103 reads (28%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLHL23 | c.65del p.T23Qfs*9 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs201368558; called by mutect2, pindel, varscan2
- KLHL29 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs987740761, COSV72086551; called by muse, mutect2, varscan2
- KRT86 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 104/319 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs531934335; called by muse, mutect2, varscan2
- L3MBTL4 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757230528, COSV53115908; called by muse, mutect2, varscan2
- LAGE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV62074504; called by muse, mutect2, varscan2
- LAMA4 | c.2888del p.K963Rfs*35 (on ENST00000230538 / NM_001105206.3; = p.K956Rfs*35 on NM_002290.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 102/296 reads (34%) | catalogued as COSV57905739; called by mutect2, varscan2
- LAMB4 | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as rs1365309430, COSV52729877; called by muse, mutect2, varscan2
- LDB3 | c.59dup p.K21Qfs*27 | Frame Shift Ins (INS) | VAF 38/164 reads (23%) | catalogued as COSV53947697; called by mutect2, pindel, varscan2
- LMBRD1 | c.754G>A p.A252T (on ENST00000649011; = p.A230T on NM_018368.4) | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs376081191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPGAT1 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.922); catalogued as COSV65351578; called by muse, mutect2, varscan2
- LRAT | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010347467, COSV60477114; called by muse, mutect2, varscan2
- LRRC18 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181964947; called by muse, mutect2, varscan2
- LRRC37A3 | c.4754C>T p.A1585V | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs375279391; called by muse, mutect2, varscan2
- LRRC8E | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1374368105; called by muse, mutect2
- LSS | c.1655G>T p.R552M | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62700324; called by muse, mutect2, varscan2
- LTBP1 | c.2218G>A p.V740I (on ENST00000404816 / NM_206943.4; = p.V414I on NM_000627.4) | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs763406365, COSV63189587; called by muse, mutect2, varscan2
- LUM | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as rs1364445609; called by muse, mutect2, varscan2
- MALT1 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs757096789, COSV61934102; called by muse, mutect2, varscan2
- MAPT | c.775G>A p.A259T (on ENST00000262410 / NM_001377265.1; = p.A184T on NM_016835.4) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as rs377597373, COSV52240437; called by muse, mutect2, varscan2
- MASTL | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1223409139; called by muse, mutect2, varscan2
- MBD5 | c.1420A>G p.M474V | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs577567411; called by muse, mutect2, varscan2
- MED12 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1228685555, COSV99048830; ClinVar: uncertain significance; called by muse, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 29/95 reads (31%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MIDEAS | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1390247827, COSV54097259; called by muse, mutect2, varscan2
- MMP15 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs760059840, COSV99539560; called by muse, mutect2, varscan2
- MNT | c.1492C>A p.L498I | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV51511413; called by muse, mutect2, varscan2
- MSLNL | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.206); catalogued as rs766692208; called by muse, mutect2, varscan2
- MTA1 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781923587; called by muse, mutect2, varscan2
- MXRA5 | c.6460C>T p.R2154W | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54226273; called by muse, mutect2, varscan2
- MYBL2 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs145901596; called by muse, varscan2
- MYCT1 | c.123_126del p.L42Yfs*14 | Frame Shift Del (DEL) | VAF 24/100 reads (24%) | catalogued as rs779254359; called by pindel, varscan2
- MYH14 | c.4180C>T p.R1394W | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1052563735, COSV51814342; called by muse, mutect2, varscan2
- MYO15A | c.10253T>C p.F3418S | Missense Mutation (SNP) | VAF 80/440 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755139806, COSV52752745; called by muse, mutect2, varscan2
- MYO9B | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as rs376402468; called by muse, mutect2, varscan2
- NBEAL2 | c.5245A>G p.M1749V | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs1317719025; called by muse, mutect2, varscan2
- NDST4 | c.1813dup p.T605Nfs*22 | Frame Shift Ins (INS) | VAF 33/90 reads (37%) | catalogued as rs1215333204; called by mutect2, pindel, varscan2
- NEDD4L | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs767136811, CM045180; ClinVar: benign; called by muse, mutect2, varscan2
- NEFM | c.2635G>A p.V879I | Missense Mutation (SNP) | VAF 103/292 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.114); catalogued as rs140995374; called by muse, mutect2, varscan2
- NEO1 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.307); catalogued as rs952837071; called by muse, mutect2, varscan2
- NOD2 | c.1515del p.S506Pfs*11 | Frame Shift Del (DEL) | VAF 54/176 reads (31%) | catalogued as rs754761524; ClinVar: uncertain significance; called by mutect2, varscan2
- NRDE2 | c.268del p.R90Gfs*69 | Frame Shift Del (DEL) | VAF 30/230 reads (13%) | catalogued as rs1249617548, COSV62963847; called by mutect2, varscan2
- NRG2 | c.1264G>A p.V422I | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs773872580, COSV56842100; called by muse, mutect2, varscan2
- NSD1 | c.3802C>T p.R1268W | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); catalogued as rs558018694; called by muse, mutect2, varscan2
- NUB1 | c.990del p.K330Nfs*2 | Frame Shift Del (DEL) | VAF 21/167 reads (13%) | catalogued as rs760102115; called by mutect2, varscan2
- OBSCN | c.20267C>T p.S6756F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs756254135; called by muse, mutect2, varscan2
- OR2M4 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1307597877; called by muse, mutect2, varscan2
- OR2T11 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780413150; called by muse, mutect2, varscan2
- OR51E1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs758137608, COSV101211577; called by muse, mutect2, varscan2
- OR5B3 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58676411; called by muse, mutect2, varscan2
- OR5W2 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV60617146; called by muse, mutect2, varscan2
- P3H4 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as COSV100821215, COSV62680589; called by muse, mutect2, varscan2
- PAFAH2 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 46/124 reads (37%) | catalogued as rs144717482; called by muse, mutect2, varscan2
- PCCA | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 133/326 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747943045, COSV66187867; called by muse, mutect2, varscan2
- PCDHA7 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV65348271; called by muse, mutect2, varscan2
- PCDHGB7 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as COSV53998269; called by muse, mutect2, varscan2
- PCSK5 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs765807770, COSV65084154; called by muse, mutect2, varscan2
- PDE8A | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373678620; called by muse, mutect2, varscan2
- PDGFRA | c.3050G>A p.G1017D | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.611); catalogued as COSV57277646; called by muse, mutect2, varscan2
- PDZD7 | c.2992_2993del p.Q998Dfs*5 | Frame Shift Del (DEL) | VAF 45/163 reads (28%) | catalogued as rs1471327428; called by mutect2, pindel
- PDZRN3 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs753223489, COSV55207940, COSV99728340; called by muse, mutect2, varscan2
- PHGR1 | c.175del p.H59Tfs*49 | Frame Shift Del (DEL) | VAF 13/104 reads (13%) | catalogued as rs748850271; called by pindel, varscan2
- PIEZO1 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 70/396 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as COSV56340707; called by muse, mutect2, varscan2
- PIP4K2A | c.941del p.P314Qfs*8 | Frame Shift Del (DEL) | VAF 8/93 reads (9%) | catalogued as rs755454854; called by mutect2, pindel
- PKLR | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 147/414 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs770747923; called by muse, mutect2, varscan2
- PLEKHG1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs138285377; called by muse, mutect2, varscan2
- PLEKHM2 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.243); catalogued as rs763611331; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | catalogued as rs953293505; called by mutect2, varscan2
- POLD1 | c.2158G>A p.V720I | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as rs1042614681, COSV70954884; called by muse, mutect2, varscan2
- PPP2R2B | c.1184T>G p.V395G (on ENST00000394409; = p.V461G on NM_181674.2) | Missense Mutation (SNP) | VAF 114/328 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs778098894, COSV60751353; called by muse, varscan2
- PPP2R3B | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as rs934114526; called by muse, mutect2, varscan2
- PRIMPOL | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV99860039; called by muse, mutect2, varscan2
- PRKDC | c.8308G>A p.V2770I | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs764298664, COSV58066880; called by muse, mutect2, varscan2
- PRPF31 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.069); catalogued as rs766301461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRRT2 | c.596A>C p.E199A | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV54888135; called by muse, varscan2
- PYGL | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 47/314 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150701003, CM117187; called by muse, mutect2, varscan2
- QSER1 | c.3091G>A p.D1031N (on ENST00000399302; = p.D1160N on NM_001076786.3) | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.926); catalogued as rs780349125; called by muse, mutect2, varscan2
- RAB14 | c.105del p.K35Nfs*18 | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | catalogued as rs1564320972; called by mutect2, varscan2
- RAB3IP | c.479G>A p.R160H (on ENST00000550536 / NM_175623.4; = p.R144H on NM_022456.5) | Missense Mutation (SNP) | VAF 103/301 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs200501608; called by muse, mutect2, varscan2
- RACK1 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV59322937; called by muse, mutect2, varscan2
- RAD54L2 | c.4181C>T p.P1394L | Missense Mutation (SNP) | VAF 105/273 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs375836463, COSV56581139; called by muse, mutect2, varscan2
- RADIL | c.2642del p.P881Lfs*110 | Frame Shift Del (DEL) | VAF 33/122 reads (27%) | catalogued as rs767679528; called by mutect2, pindel, varscan2
- RANBP17 | c.1884del p.K628Nfs*3 | Frame Shift Del (DEL) | VAF 26/132 reads (20%) | catalogued as COSV101206115; called by mutect2, pindel, varscan2
- RBBP6 | c.4462A>G p.R1488G | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as rs1177269316; called by muse, mutect2, varscan2
- RBM47 | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1390170460; called by muse, mutect2, varscan2
- RBMXL2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as rs1397269593, COSV60979380; called by muse, mutect2, varscan2
- RESP18 | c.231C>T p.H77= | Splice Region (SNP) | VAF 17/61 reads (28%) | catalogued as COSV61113621, COSV61114344; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 35/213 reads (16%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNPEP | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1392691667; called by muse, mutect2, varscan2
- ROBO3 | c.1124del p.P375Hfs*67 | Frame Shift Del (DEL) | VAF 30/108 reads (28%) | catalogued as rs1565310419, COSV67299801; called by mutect2, pindel, varscan2
- RP1 | c.3671G>A p.S1224N | Missense Mutation (SNP) | VAF 78/370 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs780130777; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 50/160 reads (31%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA2 | c.2053C>T p.R685* | Nonsense Mutation (SNP) | VAF 28/196 reads (14%) | catalogued as rs1195326963; called by muse, mutect2, varscan2
- RRAS2 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56329970, COSV56331263; called by muse, mutect2, varscan2
- SAFB2 | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368944878; called by muse, mutect2
- SALL3 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs371147449; called by muse, mutect2, varscan2
- SBNO2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as rs370217842; called by muse, mutect2, varscan2
- SCLY | c.460G>A p.D154N (on ENST00000651534; = p.D146N on NM_016510.7) | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs373610798; called by muse, mutect2, varscan2
- SCN11A | c.3727G>A p.V1243M | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775046299; ClinVar: uncertain significance; called by muse, mutect2
- SERPINA9 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 42/91 reads (46%) | catalogued as COSV54076352; called by muse, mutect2, varscan2
- SETBP1 | c.3233C>T p.T1078M | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs375939479; called by muse, mutect2, varscan2
- SETD5 | c.3257del p.G1086Efs*58 | Frame Shift Del (DEL) | VAF 70/222 reads (32%) | catalogued as COSV56715497; called by mutect2, pindel, varscan2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 50/128 reads (39%) | catalogued as rs747473028; called by mutect2, varscan2
- SH3RF3 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1183906650; called by muse, mutect2, varscan2
- SHB | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99081197; called by muse, mutect2, varscan2
- SHD | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV73378703; called by muse, mutect2, varscan2
- SHOX | c.728dup p.P244Afs*147 | Frame Shift Ins (INS) | VAF 135/411 reads (33%) | catalogued as rs757845999; called by mutect2, pindel, varscan2
- SKIV2L | c.2446del p.E816Rfs*3 | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | catalogued as rs768446878; called by mutect2, pindel, varscan2
- SLC16A7 | c.696del p.V233Lfs*5 | Frame Shift Del (DEL) | VAF 47/167 reads (28%) | catalogued as COSV99675946; called by mutect2, pindel, varscan2
- SLC16A7 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1476635604; called by muse, mutect2, varscan2
- SLC22A16 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1272718304; called by muse, mutect2, varscan2
- SLC25A37 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409826647, COSV99263987; called by muse, mutect2, varscan2
- SLC4A1AP | c.1887del p.K630Sfs*9 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | catalogued as rs1398113963; called by mutect2, pindel, varscan2
- SLC9A7 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs999568091, COSV60382987; called by muse, mutect2, varscan2
- SMAD6 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as rs776644944, COSV56594209; called by muse, mutect2, varscan2
- SMPD4 | c.2414G>A p.G805D (on ENST00000409031 / NM_017951.4; = p.G776D on NM_017751.4) | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); catalogued as rs762144739; called by muse, mutect2, varscan2
- SNX18 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1313711976; called by muse, mutect2, varscan2
- SOX6 | c.1434A>G p.L478= (on ENST00000528429 / NM_001145819.2; = p.L437= on NM_017508.3) | Splice Region (SNP) | VAF 46/147 reads (31%) | catalogued as rs1206619305; called by muse, mutect2, varscan2
- SOX8 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs754265113; called by muse, mutect2, varscan2
- SPECC1 | c.2351+1G>A p.X784_splice | Splice Site (SNP) | VAF 47/128 reads (37%) | catalogued as COSV54958779; called by muse, mutect2, varscan2
- SPIRE1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1453744342, COSV100563549; called by muse, mutect2, varscan2
- SPOP | c.223G>C p.G75R | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100753063, COSV61654496, COSV61656168; called by muse, mutect2, varscan2
- SPRING1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs959641965; called by muse, mutect2, varscan2
- SPTBN2 | c.5566-5C>T | Splice Region (SNP) | VAF 21/55 reads (38%) | catalogued as rs192159470, COSV59450625; called by muse, mutect2, varscan2
- SPTLC3 | c.422T>C p.M141T | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs201328729; called by muse, mutect2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | catalogued as rs748467821; called by mutect2, varscan2
- SRGAP1 | c.2732G>A p.R911H | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.742); catalogued as rs759843034; called by muse, mutect2, varscan2
- SRRM2 | c.5723G>A p.R1908Q | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs1567239444; called by muse, mutect2
- SRSF11 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV63937383; called by muse, mutect2, varscan2
- SSC5D | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs945743306, COSV67476280; called by muse, mutect2, varscan2
- SSH2 | c.2756del p.P919Qfs*12 | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | catalogued as rs752567808; called by mutect2, pindel, varscan2
- SSU72 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as rs1043936136; called by muse, mutect2, varscan2
- STAT5B | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 126/383 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV53181153; called by muse, mutect2, varscan2
- SUCLA2 | c.271+2T>C p.X91_splice | Splice Site (SNP) | VAF 54/153 reads (35%) | catalogued as COSV66222458; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | catalogued as rs770033147; called by mutect2, varscan2
- SYNE1 | c.707G>A p.R236Q (on ENST00000367255 / NM_182961.4; = p.R243Q on NM_033071.3) | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs200704755, COSV55056838; called by muse, mutect2
- SYNJ2 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866906958; called by muse, mutect2, varscan2
- SYNPO2 | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV61114508; called by muse, mutect2
- TACC1 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 103/275 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs779300910, COSV52523138; called by muse, mutect2, varscan2
- TASOR | c.661T>C p.Y221H | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs370143911, COSV62927946; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 44/109 reads (40%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF3 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs147142249; called by muse, mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 18/122 reads (15%) | catalogued as rs745872748; called by mutect2, varscan2
- TDRD15 | c.1073G>A p.C358Y | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV68267146; called by muse, mutect2
- TEX52 | c.402del p.T135Rfs*17 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs752045113; called by mutect2, pindel, varscan2
- TF | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1341678783, COSV53920087; called by muse, mutect2, varscan2
- THOP1 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs772131341; called by muse, mutect2, varscan2
- TMEM132C | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 111/306 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs750892295, COSV70661317, COSV70672772; called by muse, mutect2, varscan2
- TMEM168 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754406772; called by muse, mutect2, varscan2
- TMPRSS11D | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.819); catalogued as COSV52225924; called by muse, mutect2, varscan2
- TOP3B | c.2293C>T p.R765W | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs1223815244; called by mutect2, varscan2
- TOPORS | c.2556_2557del p.E852Dfs*20 | Frame Shift Del (DEL) | VAF 54/168 reads (32%) | catalogued as rs527236116; called by pindel, varscan2
- TOR4A | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs1362147983; called by muse, varscan2
- TOX2 | c.330del p.N111Tfs*23 (on ENST00000358131 / NM_001098798.2; = p.N60Tfs*23 on NM_032883.3) | Frame Shift Del (DEL) | VAF 36/287 reads (13%) | catalogued as COSV57885225; called by mutect2, pindel, varscan2
- TRABD2B | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs936516501, COSV71211357; called by muse, mutect2, varscan2
- TRIM17 | c.821dup p.T275Nfs*14 | Frame Shift Ins (INS) | VAF 48/160 reads (30%) | catalogued as rs758372115; called by mutect2, varscan2
- TRIM42 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV53880832, COSV53887344; called by muse, mutect2, varscan2
- TRIM71 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV101070549; called by muse, mutect2, varscan2
- TRIP11 | c.5888C>T p.A1963V | Missense Mutation (SNP) | VAF 163/417 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50955475; called by muse, mutect2, varscan2
- TRPM5 | c.1433G>A p.C478Y | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs970644042; called by muse, mutect2, varscan2
- TRRAP | c.2990C>A p.T997N | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100722563; called by muse, mutect2, varscan2
- TSEN2 | c.265T>C p.W89R | Missense Mutation (SNP) | VAF 118/321 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs753594243; called by muse, mutect2, varscan2
- TTC9 | c.282del p.E96Nfs*15 | Frame Shift Del (DEL) | VAF 38/119 reads (32%) | catalogued as rs751516988; called by mutect2, varscan2
- TTC9B | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV53421470; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.65501G>A p.R21834H (on ENST00000591111; = p.R14410H on NM_003319.4) | Missense Mutation (SNP) | VAF 45/137 reads (33%) | PolyPhen possibly damaging (0.869); catalogued as rs370257707; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.58928A>G p.H19643R (on ENST00000591111; = p.H12219R on NM_003319.4) | Missense Mutation (SNP) | VAF 130/347 reads (37%) | PolyPhen benign (0.173); catalogued as rs769740117; called by muse, mutect2, varscan2
- TXNDC11 | c.2825C>T p.A942V (on ENST00000356957 / NM_001303447.2; = p.A915V on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs570323012, COSV99297983; called by muse, mutect2, varscan2
- TYK2 | c.2669C>T p.T890M | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1303144673, COSV53384829; called by muse, mutect2, varscan2
- UBAC1 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1339360847; called by muse, mutect2, varscan2
- UBXN6 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1449249192; called by mutect2, varscan2
- UNC5B | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs762851637, COSV58975420; called by muse, mutect2, varscan2
- UNC79 | c.5855G>A p.R1952H (on ENST00000393151 / NM_001346218.2; = p.R1775H on NM_020818.5) | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs757122850; called by muse, mutect2, varscan2
- URB1 | c.2482del p.L828Wfs*214 | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | catalogued as rs1347436818; called by mutect2, pindel
- USP20 | c.2528T>C p.I843T | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs374928171; called by muse, mutect2, varscan2
- USP35 | c.1597C>T p.H533Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1265456428; called by muse, mutect2, varscan2
- UST | c.1117del p.L373* | Frame Shift Del (DEL) | VAF 82/216 reads (38%) | catalogued as rs760552029, COSV66551382; called by mutect2, varscan2
- VEZT | c.225G>C p.Q75H | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV54142739; called by muse, mutect2, varscan2
- VILL | c.1438del p.H480Tfs*11 | Frame Shift Del (DEL) | VAF 99/304 reads (33%) | catalogued as rs753585188; called by mutect2, varscan2
- VPS33B | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 35/362 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs1567223730; called by muse, mutect2, varscan2
- VPS37B | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as rs1271916221; called by muse, mutect2, varscan2
- VPS41 | c.1528_1529del p.L510Tfs*2 | Frame Shift Del (DEL) | VAF 37/97 reads (38%) | catalogued as rs1466204626; called by mutect2, pindel, varscan2
- WDR7 | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs748352333, COSV54358631; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WTAP | c.485G>C p.R162P | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV61610446, COSV61610540; called by muse, mutect2, varscan2
- XRCC3 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs1239300559, COSV57974871; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 54/301 reads (18%) | catalogued as rs779864368; called by mutect2, varscan2
- ZDHHC5 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99762643; called by muse, mutect2, varscan2
- ZNF257 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs780971566, COSV71306463; called by muse, mutect2, varscan2
- ZNF333 | c.1786G>A p.G596R | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs140135561; called by muse, mutect2, varscan2
- ZNF469 | c.3134C>T p.A1045V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs1474082425; called by muse, mutect2, varscan2
- ZNF646 | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1200804214; called by muse, mutect2, varscan2
- ZNF74 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs766452058; called by muse, mutect2, varscan2
- ZNF878 | c.507del p.K169Nfs*44 | Frame Shift Del (DEL) | VAF 36/200 reads (18%) | catalogued as rs773648883, COSV72155908; called by pindel, varscan2
- ABCF3 | c.298T>G p.Y100D | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD18 | c.488del p.N163Mfs*7 (on ENST00000398965 / NM_001039717.2; = p.N36Mfs*7 on NM_025097.2 and 10 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 42/147 reads (29%) | called by mutect2, pindel, varscan2
- ACTN1 | c.1009A>G p.N337D | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- ACTN4 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 145/408 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ACVR1 | c.338C>A p.S113Y | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADCY3 | c.1120T>C p.C374R | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ADGRG6 | c.2348A>G p.K783R | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADORA2A | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF1 | c.1714del p.R572Gfs*74 | Frame Shift Del (DEL) | VAF 35/117 reads (30%) | called by mutect2, pindel, varscan2
- AHDC1 | c.1758del p.K586Nfs*37 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- AIF1 | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.159); called by muse, varscan2
- ALOX5 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- AMPD1 | c.727del p.M243* | Frame Shift Del (DEL) | VAF 47/323 reads (15%) | called by mutect2, pindel, varscan2
- AMY2B | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 50/292 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ANKRD11 | c.791A>G p.N264S | Missense Mutation (SNP) | VAF 71/325 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ANKRD26 | c.4101A>T p.L1367F | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- ANKRD36C | c.2834del p.K945Sfs*17 | Frame Shift Del (DEL) | VAF 66/231 reads (29%) | called by mutect2, pindel, varscan2
- AP2S1 | c.327+2T>A p.X109_splice | Splice Site (SNP) | VAF 17/127 reads (13%) | called by muse, mutect2, varscan2
- API5 | c.856-2A>G p.X286_splice | Splice Site (SNP) | VAF 35/110 reads (32%) | called by muse, mutect2, varscan2
- AR | c.2647A>G p.I883V | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ARF1 | c.48dup p.E17Rfs*22 | Frame Shift Ins (INS) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- ARHGAP19 | c.1109A>T p.E370V | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP5 | c.1720A>G p.S574G | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 69/217 reads (32%) | called by mutect2, varscan2
- ATAD1 | c.824del p.N275Mfs*8 | Frame Shift Del (DEL) | VAF 49/198 reads (25%) | called by mutect2, pindel, varscan2
- ATAD5 | c.3890dup p.N1297Kfs*9 | Frame Shift Ins (INS) | VAF 34/214 reads (16%) | called by mutect2, pindel, varscan2
- ATF7IP | c.2363C>A p.P788H | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATG9A | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- ATN1 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ATP2C2 | c.2681del p.P894Rfs*19 | Frame Shift Del (DEL) | VAF 29/91 reads (32%) | called by mutect2, pindel, varscan2
- ATP7A | c.680dup p.Q228Afs*3 | Frame Shift Ins (INS) | VAF 22/173 reads (13%) | called by mutect2, pindel, varscan2
- AVPR1A | c.1053del p.F351Lfs*19 | Frame Shift Del (DEL) | VAF 70/226 reads (31%) | called by mutect2, pindel, varscan2
- BICD1 | c.2765-6T>G | Splice Region (SNP) | VAF 42/121 reads (35%) | called by muse, mutect2, varscan2
- BICRA | c.1597del p.H533Tfs*191 | Frame Shift Del (DEL) | VAF 11/104 reads (11%) | called by mutect2, pindel, varscan2
- BSPH1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- C1orf56 | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- C6orf132 | c.2960C>T p.P987L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CADPS | c.231del p.L78Cfs*20 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | called by mutect2, pindel, varscan2
- CAPN1 | c.1112A>G p.Y371C | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- CATSPERB | c.673T>A p.F225I | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- CCAR2 | c.357+1G>C p.X119_splice | Splice Site (SNP) | VAF 48/150 reads (32%) | called by muse, mutect2, varscan2
- CCDC88A | c.1517del p.K506Rfs*22 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- CCN2 | c.886del p.H296Tfs*18 | Frame Shift Del (DEL) | VAF 126/358 reads (35%) | called by mutect2, varscan2
- CCNB3 | c.1313T>C p.L438S | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- CCNE2 | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD300A | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD93 | c.943del p.A315Pfs*273 | Frame Shift Del (DEL) | VAF 33/83 reads (40%) | called by mutect2, pindel, varscan2
- CDAN1 | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 105/305 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CDKAL1 | c.865A>T p.R289W | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDYL2 | c.452del p.K151Sfs*31 | Frame Shift Del (DEL) | VAF 18/166 reads (11%) | called by mutect2, pindel, varscan2
- CELSR1 | c.4646C>T p.P1549L | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP170B | c.4562A>G p.D1521G (on ENST00000453495; = p.D1450G on NM_015005.3) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CEP350 | c.9166A>G p.R3056G | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CEP68 | c.949A>T p.K317* | Nonsense Mutation (SNP) | VAF 60/151 reads (40%) | called by muse, mutect2, varscan2
- CHD4 | c.4928C>A p.P1643H (on ENST00000357008 / NM_001363606.2; = p.P1654H on NM_001273.5) | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 27/100 reads (27%) | called by mutect2, pindel, varscan2
- CHD9 | c.5489C>T p.A1830V | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2
- CILP2 | c.1927T>A p.F643I | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CKAP2L | c.1518del p.E507Kfs*19 | Frame Shift Del (DEL) | VAF 34/225 reads (15%) | called by mutect2, varscan2
- CLMP | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CMYA5 | c.12160T>C p.C4054R | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CNEP1R1 | c.271G>A p.A91T (on ENST00000427478 / NM_001281789.1; = p.A108T on NM_153261.5) | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); called by muse, mutect2
- COL4A5 | c.1943T>C p.I648T | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- COL4A5 | c.2603C>T p.P868L | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPA | c.2568T>A p.D856E | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COPS4 | c.815T>C p.I272T | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CPT1C | c.621G>T p.Q207H | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CRIM1 | c.2144G>A p.C715Y | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYBG3 | c.7301A>G p.Y2434C | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAPK1 | c.3822del p.Y1275Tfs*31 | Frame Shift Del (DEL) | VAF 28/93 reads (30%) | called by mutect2, pindel, varscan2
- DCAF6 | c.499A>T p.R167W | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DDHD1 | c.780G>T p.W260C (on ENST00000323669; = p.W457C on NM_030637.3) | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX56 | c.60+2T>G p.X20_splice | Splice Site (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- DIAPH1 | c.2104C>A p.P702T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMBT1 | c.5300del p.L1767Wfs*3 (on ENST00000338354 / NM_001377530.1; = p.L1010Wfs*3 on NM_004406.3) | Frame Shift Del (DEL) | VAF 56/197 reads (28%) | called by mutect2, pindel, varscan2
- DMTN | c.364del p.R122Gfs*109 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | called by mutect2, pindel, varscan2
- DNAH3 | c.9262G>A p.A3088T | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNMT1 | c.853_855del p.K285del | In Frame Del (DEL) | VAF 54/164 reads (33%) | called by pindel, varscan2
- DOCK3 | c.3386del p.N1129Mfs*11 | Frame Shift Del (DEL) | VAF 29/69 reads (42%) | called by mutect2, pindel, varscan2
- DPP3 | c.1340T>C p.V447A | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DTX3 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DUSP18 | c.53G>A p.S18N | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- DYRK3 | c.1550T>C p.L517S | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- EBF4 | c.768del p.C257Afs*63 (on ENST00000609451; = p.C253Afs*63 on NM_001110514.1) | Frame Shift Del (DEL) | VAF 52/154 reads (34%) | called by mutect2, pindel, varscan2
- EEA1 | c.2282C>T p.T761I | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- EGLN3 | c.357+2T>C p.X119_splice | Splice Site (SNP) | VAF 30/234 reads (13%) | called by muse, mutect2, varscan2
- EGR4 | c.1147del p.A383Lfs*8 (on ENST00000545030; = p.A280Lfs*8 on NM_001965.4) | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | called by mutect2, pindel, varscan2
- EIF2AK2 | c.721del p.R241Dfs*12 | Frame Shift Del (DEL) | VAF 23/99 reads (23%) | called by mutect2, pindel, varscan2
- EMD | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 92/269 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- EPPK1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERCC6L2 | c.3335del p.L1112* | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- ESCO1 | c.788A>T p.K263M | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ETFB | c.472del p.D158Tfs*3 | Frame Shift Del (DEL) | VAF 31/237 reads (13%) | called by mutect2, pindel, varscan2
- ETFB | c.203C>A p.P68H | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAM120A | c.805G>C p.V269L | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FAM153B | c.863G>C p.S288T (on ENST00000253490; = p.S211T on NM_001265615.1) | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- FAM227B | c.528A>T p.L176F | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- FAM83E | c.1172A>G p.N391S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM98A | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- FAT3 | c.9640C>T p.Q3214* | Nonsense Mutation (SNP) | VAF 75/193 reads (39%) | called by muse, mutect2, varscan2
- FEM1A | c.616A>G p.K206E | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FEZF1 | c.586dup p.T196Nfs*8 | Frame Shift Ins (INS) | VAF 26/183 reads (14%) | called by mutect2, pindel, varscan2
- FIGLA | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- FNDC3B | c.809A>C p.K270T | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- FOXE1 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FYTTD1 | c.696_697del p.S233Yfs*2 | Frame Shift Del (DEL) | VAF 46/198 reads (23%) | called by mutect2, pindel, varscan2
- FZD10 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2
- GABRA1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GBP1 | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- GDF15 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GOLGA4 | c.3261del p.E1088Kfs*3 | Frame Shift Del (DEL) | VAF 54/215 reads (25%) | called by mutect2, pindel, varscan2
- GPR150 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GPR180 | c.1143del p.F381Lfs*12 | Frame Shift Del (DEL) | VAF 29/179 reads (16%) | called by mutect2, varscan2
- GSG1L2 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- GSTM2 | c.345C>A p.C115* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- GTF3C1 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H4C8 | c.238A>T p.K80* | Nonsense Mutation (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- HAUS7 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 139/401 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEATR3 | c.1523A>C p.H508P | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- HECTD1 | c.1932A>G p.K644= | Splice Region (SNP) | VAF 26/58 reads (45%) | called by muse, varscan2
- HFE | c.904T>C p.S302P | Missense Mutation (SNP) | VAF 71/469 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HLA-DQB2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- HOXB7 | c.152T>G p.F51C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HRNR | c.5746A>G p.S1916G | Missense Mutation (SNP) | VAF 65/1301 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2
- HSDL2 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR1B | c.783del p.S263Pfs*25 | Frame Shift Del (DEL) | VAF 25/187 reads (13%) | called by mutect2, varscan2
- ICE1 | c.119T>C p.L40S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGKV3D-15 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 157/248 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- IL4R | c.2051A>G p.E684G | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- INF2 | c.1587del p.V530Wfs*28 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, varscan2
- INPP5F | c.3070_3071del p.Q1024Vfs*5 | Frame Shift Del (DEL) | VAF 94/294 reads (32%) | called by pindel, varscan2
- INPPL1 | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- INSIG1 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 87/287 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IREB2 | c.696dup p.K233* | Frame Shift Ins (INS) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- IRF2 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRX5 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- JADE1 | c.1707A>G p.I569M | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- JAK1 | c.2564_2565del p.I855Sfs*9 | Frame Shift Del (DEL) | VAF 48/168 reads (29%) | called by mutect2, pindel, varscan2
- JAK1 | c.425del p.K142Rfs*26 | Frame Shift Del (DEL) | VAF 85/236 reads (36%) | called by mutect2, varscan2
- KCNK3 | c.683T>A p.I228N | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCTD21 | c.236T>A p.L79Q | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- KIAA0753 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- KIAA1841 | c.794T>A p.M265K | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- KIF1B | c.4744G>A p.A1582T (on ENST00000377086 / NM_001365952.1; = p.A1536T on NM_015074.3) | Missense Mutation (SNP) | VAF 141/397 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- KIF4A | c.1313G>A p.R438K | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF7 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIN | c.607G>T p.V203F | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); called by muse, varscan2
- KLC1 | c.1411G>A p.G471R | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL26 | c.920A>T p.D307V | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2
- KMT2B | c.1589C>A p.P530H | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KMT2B | c.3302del p.P1101Lfs*81 | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | called by mutect2, pindel, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 21/138 reads (15%) | called by mutect2, pindel, varscan2
- KRT10 | c.194dup p.C66Lfs*19 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- KRT81 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- LAMA2 | c.2426G>T p.C809F | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LETM2 | c.596A>T p.K199I (on ENST00000379957 / NM_001286819.2; = p.K152I on NM_001199659.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LHCGR | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIMA1 | c.605A>G p.E202G | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- LIPC | c.783A>C p.R261S | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LMBRD2 | c.1214G>A p.C405Y | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMOD3 | c.866del p.L289* | Frame Shift Del (DEL) | VAF 65/222 reads (29%) | called by mutect2, pindel, varscan2
- LRFN1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- LRP6 | c.3346C>G p.L1116V | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.719); called by muse, mutect2
- LRRTM3 | c.1090del p.S364Vfs*86 | Frame Shift Del (DEL) | VAF 60/227 reads (26%) | called by mutect2, pindel, varscan2
- LVRN | c.269del p.P90Rfs*26 | Frame Shift Del (DEL) | VAF 23/158 reads (15%) | called by mutect2, pindel, varscan2
- MAN2B2 | c.1183del p.R395Vfs*37 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- MAP1B | c.247G>C p.V83L | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MASP1 | c.1165T>A p.Y389N | Missense Mutation (SNP) | VAF 116/328 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- MCCD1 | c.104dup p.N35Kfs*32 | Frame Shift Ins (INS) | VAF 51/125 reads (41%) | called by mutect2, pindel, varscan2
- MCM8 | c.265A>G p.S89G | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); called by mutect2, varscan2
- MCTP1 | c.2732G>A p.W911* | Nonsense Mutation (SNP) | VAF 68/250 reads (27%) | called by muse, mutect2, varscan2
- MEIS2 | c.547del p.M183Cfs*73 (on ENST00000561208 / NM_170675.5; = p.M170Cfs*73 on NM_002399.3) | Frame Shift Del (DEL) | VAF 21/218 reads (10%) | called by mutect2, pindel, varscan2
- MFSD6 | c.1497del p.F499Lfs*8 | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | called by mutect2, pindel, varscan2
- MGAT3 | c.1336T>C p.Y446H | Missense Mutation (SNP) | VAF 25/310 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- MGAT5B | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGRN1 | c.1353del p.D452Tfs*46 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | called by mutect2, pindel, varscan2
- MKS1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 123/382 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMADHC | c.702del p.F234Lfs*19 | Frame Shift Del (DEL) | VAF 68/222 reads (31%) | called by mutect2, pindel, varscan2
- MROH9 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MRPS27 | c.641A>T p.K214I | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- MUC13 | c.708G>T p.M236I | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MUC16 | c.4082del p.P1361Qfs*59 | Frame Shift Del (DEL) | VAF 66/200 reads (33%) | called by mutect2, pindel, varscan2
- MYBL2 | c.596del p.P199Qfs*27 | Frame Shift Del (DEL) | VAF 65/209 reads (31%) | called by pindel, varscan2
- MYCBP2 | c.11233A>G p.T3745A (on ENST00000357337; = p.T3783A on NM_015057.5) | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYCL | c.256T>A p.Y86N (on ENST00000372816 / NM_001033081.3; = p.Y116N on NM_005376.5) | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MYOT | c.1415A>T p.N472I | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- NAPSA | c.946C>A p.L316M | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- NAV1 | c.4248G>T p.K1416N | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- NEIL3 | c.513del p.K171Nfs*7 | Frame Shift Del (DEL) | VAF 72/232 reads (31%) | called by mutect2, pindel, varscan2
- NHSL1 | c.2728_2731del p.S910Lfs*11 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | called by pindel, varscan2
- NINL | c.628del p.V210Wfs*7 | Frame Shift Del (DEL) | VAF 32/149 reads (21%) | called by mutect2, pindel, varscan2
- NLRC5 | c.2891T>G p.L964R | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- NOP16 | c.86dup p.A30Gfs*18 | Frame Shift Ins (INS) | VAF 39/270 reads (14%) | called by mutect2, pindel, varscan2
- NOS1 | c.125T>C p.I42T | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPDC1 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRL | c.643T>A p.Y215N | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NTMT1 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NTRK2 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 62/499 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- NUAK2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP210L | c.5483T>G p.I1828S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2
- NYX | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- OLFML2B | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPA1 | c.2865T>A p.N955K (on ENST00000361510 / NM_130837.3; = p.N900K on NM_015560.3) | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- OPRK1 | c.386T>C p.V129A | Missense Mutation (SNP) | VAF 99/284 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OR10G2 | c.193T>C p.Y65H | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- OR1K1 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- OR2A2 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52B6 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OSBPL11 | c.1276A>G p.I426V | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OSBPL3 | c.35A>T p.Q12L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- OSBPL6 | c.988-2A>G p.X330_splice | Splice Site (SNP) | VAF 109/320 reads (34%) | called by muse, mutect2, varscan2
- OTOR | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OXCT2 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- OXSR1 | c.917A>G p.Q306R | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- P4HA1 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PARD6B | c.383del p.K128Sfs*4 | Frame Shift Del (DEL) | VAF 34/181 reads (19%) | called by mutect2, pindel, varscan2
- PARP10 | c.3041A>G p.D1014G | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- PATJ | c.5100del p.D1701Ifs*8 | Frame Shift Del (DEL) | VAF 60/223 reads (27%) | called by mutect2, pindel, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 43/328 reads (13%) | called by pindel, varscan2
- PCARE | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- PCARE | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- PCED1A | c.332A>G p.Y111C | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PDCD6IP | c.100del p.E34Kfs*36 | Frame Shift Del (DEL) | VAF 33/103 reads (32%) | called by mutect2, pindel, varscan2
- PDK2 | c.943del p.Q315Sfs*142 | Frame Shift Del (DEL) | VAF 16/148 reads (11%) | called by mutect2, pindel
- PFAS | c.3414G>T p.R1138S | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by mutect2, varscan2
- PHEX | c.407A>T p.K136I | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PID1 | c.394G>A p.A132T (on ENST00000354069 / NM_001330156.1; = p.A130T on NM_017933.5) | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PJA1 | c.1705G>A p.A569T (on ENST00000361478 / NM_145119.4; = p.A381T on NM_022368.5) | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PKMYT1 | c.294C>A p.D98E | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLA2G4A | c.1081A>T p.T361S | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHH2 | c.645A>G p.I215M | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLS3 | c.1238A>T p.N413I | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2
- PPFIA3 | c.899A>G p.D300G | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PPP2R3C | c.1208C>A p.P403H | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- PROK1 | c.233G>A p.C78Y | Missense Mutation (SNP) | VAF 145/393 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMC5 | c.361T>A p.Y121N | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PSMD12 | c.1118T>A p.I373K | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PTPN4 | c.788T>A p.F263Y | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- R3HDM2 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 44/109 reads (40%) | called by muse, mutect2, varscan2
- RALGDS | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RANBP3L | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- RBMS1 | c.15G>C p.W5C | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- RETREG1 | c.1109C>T p.P370L (on ENST00000306320 / NM_001034850.2; = p.P229L on NM_019000.4) | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- RETSAT | c.65T>A p.L22* | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- RFX2 | c.423dup p.S142Efs*35 | Frame Shift Ins (INS) | VAF 44/138 reads (32%) | called by mutect2, pindel, varscan2
- RGL2 | c.1114del p.E372Kfs*34 | Frame Shift Del (DEL) | VAF 37/157 reads (24%) | called by mutect2, pindel, varscan2
- RHBDD2 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RIMKLB | c.366G>T p.L122F | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RNF126 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RNF225 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 113/287 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- ROBO4 | c.1384A>G p.R462G | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ROM1 | c.173A>C p.Q58P | Missense Mutation (SNP) | VAF 135/379 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROS1 | c.3053T>C p.V1018A | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- RPS6KA5 | c.1715A>G p.K572R | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- RPTOR | c.3168G>T p.K1056N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SALL3 | c.2727del p.S910Afs*58 | Frame Shift Del (DEL) | VAF 44/146 reads (30%) | called by mutect2, pindel, varscan2
- SAMD5 | c.289del p.E97Sfs*27 | Frame Shift Del (DEL) | VAF 44/114 reads (39%) | called by mutect2, pindel, varscan2
- SARM1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SCAF1 | c.3540del p.T1181Pfs*28 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | called by mutect2, varscan2
- SDF2L1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- SDR39U1 | c.206+5G>A | Splice Region (SNP) | VAF 107/278 reads (38%) | called by muse, mutect2, varscan2
- SEMA4C | c.2271del p.P759Lfs*36 | Frame Shift Del (DEL) | VAF 37/208 reads (18%) | called by pindel, varscan2
- SEMA4G | c.2068A>G p.I690V (on ENST00000370250; = p.I695V on NM_017893.3) | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA6D | c.2278G>A p.D760N (on ENST00000316364 / NM_153618.2; = p.D698N on NM_020858.2) | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- SERPINF2 | c.1437del p.M480Wfs*32 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | called by mutect2, pindel, varscan2
- SETD3 | c.1613T>C p.I538T | Missense Mutation (SNP) | VAF 117/339 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SGO2 | c.1946A>C p.K649T | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2
- SGSH | c.1340A>T p.E447V | Missense Mutation (SNP) | VAF 145/411 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLEC9 | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2
- SIN3A | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 37/264 reads (14%) | called by muse, mutect2, varscan2
- SKAP2 | c.1011G>T p.W337C | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC16A8 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2
- SLC17A9 | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC18A2 | c.791-2A>G p.X264_splice | Splice Site (SNP) | VAF 53/152 reads (35%) | called by muse, mutect2, varscan2
- SLC25A25 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC34A1 | c.63del p.H22Mfs*2 | Frame Shift Del (DEL) | VAF 129/422 reads (31%) | called by mutect2, pindel, varscan2
- SLC37A1 | c.1526T>C p.L509P | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC39A5 | c.1061A>G p.Q354R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC39A9 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC48A1 | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- SLC4A8 | c.2515G>T p.G839C | Missense Mutation (SNP) | VAF 94/285 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A4 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 138/379 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- SLC7A4 | c.1869del p.S624Afs*14 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- SLFN14 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2
- SLFNL1 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SMARCA1 | c.2501del p.K834Rfs*50 | Frame Shift Del (DEL) | VAF 43/147 reads (29%) | called by mutect2, pindel, varscan2
- SMC1B | c.1076T>A p.L359* | Nonsense Mutation (SNP) | VAF 28/182 reads (15%) | called by muse, varscan2
- SOGA1 | c.4977del p.S1660Afs*18 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by mutect2, pindel
- SOX3 | c.656A>T p.K219M | Missense Mutation (SNP) | VAF 107/298 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SP100 | c.2300T>C p.L767P | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- SPAG8 | c.50T>C p.L17S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2
- SPEN | c.1430A>G p.Q477R | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPG11 | c.3794G>A p.S1265N | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPTB | c.50G>T p.S17I | Missense Mutation (SNP) | VAF 139/443 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- SSTR2 | c.42G>A p.W14* | Nonsense Mutation (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- STAB1 | c.5413-6G>A | Splice Region (SNP) | VAF 65/176 reads (37%) | called by muse, mutect2, varscan2
- STK35 | c.686C>A p.A229E | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STK38 | c.1146del p.F382Lfs*70 | Frame Shift Del (DEL) | VAF 47/157 reads (30%) | called by mutect2, pindel, varscan2
- STX2 | c.756del p.A253Lfs*14 (on ENST00000392373 / NM_194356.4; = p.A253Lfs*12 on NM_001980.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 61/165 reads (37%) | called by mutect2, pindel, varscan2
- SUGP2 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SYNE1 | c.2094G>T p.K698N (on ENST00000367255 / NM_182961.4; = p.K705N on NM_033071.3) | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF7 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TASOR | c.338del p.F113Sfs*4 | Frame Shift Del (DEL) | VAF 13/98 reads (13%) | called by mutect2, pindel
- TBL1XR1 | c.377del p.N126Mfs*16 | Frame Shift Del (DEL) | VAF 55/148 reads (37%) | called by mutect2, pindel, varscan2
- THOC1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- THY1 | c.205dup p.V69Gfs*3 | Frame Shift Ins (INS) | VAF 46/315 reads (15%) | called by mutect2, pindel, varscan2
- TLL1 | c.301A>G p.M101V | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- TM4SF4 | c.60del p.F20Lfs*16 | Frame Shift Del (DEL) | VAF 25/144 reads (17%) | called by mutect2, pindel, varscan2
- TM9SF3 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TMED10 | c.279dup p.K94Efs*7 | Frame Shift Ins (INS) | VAF 62/218 reads (28%) | called by mutect2, pindel, varscan2
- TMEM104 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM175 | c.154-2A>G p.X52_splice | Splice Site (SNP) | VAF 52/378 reads (14%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.381del p.L128Cfs*8 (on ENST00000648592; = p.L94Cfs*8 on NM_182973.2) | Frame Shift Del (DEL) | VAF 51/186 reads (27%) | called by mutect2, pindel, varscan2
- TNPO3 | c.2382del p.S794Rfs*3 | Frame Shift Del (DEL) | VAF 45/134 reads (34%) | called by mutect2, pindel, varscan2
- TP53I13 | c.580C>G p.P194A | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TRAM2 | c.856T>A p.F286I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRIM42 | c.1220A>G p.K407R | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRMT10C | c.19del p.M7* | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- TSC22D1 | c.2796T>G p.S932R | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.193); called by muse, mutect2
- TSC22D1 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); called by muse, mutect2
- TSPAN17 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- TSPAN6 | c.604A>G p.M202V | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, varscan2
- TTL | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TTN | c.99745G>C p.V33249L (on ENST00000591111; = p.V25825L on NM_003319.4) | Missense Mutation (SNP) | VAF 103/241 reads (43%) | PolyPhen benign (0.318); called by muse, mutect2, varscan2
- TTN | c.9931T>C p.C3311R (on ENST00000591111; = p.C3265R on NM_003319.4) | Missense Mutation (SNP) | VAF 82/207 reads (40%) | PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- TUBA1C | c.1022T>C p.I341T | Missense Mutation (SNP) | VAF 63/439 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- UBD | c.353T>C p.M118T | Missense Mutation (SNP) | VAF 84/277 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ULK4 | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.355); called by muse, mutect2
- UPF2 | c.3712C>T p.R1238C | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- USH2A | c.10978G>A p.A3660T | Missense Mutation (SNP) | VAF 126/341 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- USP13 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- USP40 | c.-19-4del | Splice Region (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- USP47 | c.3935G>T p.G1312V (on ENST00000399455 / NM_001372095.1; = p.G1224V on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UTF1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- VAMP8 | c.181A>G p.T61A | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2
- VCPKMT | c.485T>A p.I162N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- VPS18 | c.1489G>C p.E497Q | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- VWF | c.7125C>G p.C2375W | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDR33 | c.1609del p.T537Hfs*76 | Frame Shift Del (DEL) | VAF 22/141 reads (16%) | called by mutect2, pindel, varscan2
- WDR5 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WIPF2 | c.570del p.T191Hfs*47 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | called by mutect2, pindel, varscan2
- WRN | c.1970A>C p.E657A | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- XPO6 | c.390dup p.T131Yfs*2 | Frame Shift Ins (INS) | VAF 34/200 reads (17%) | called by mutect2, pindel, varscan2
- XPO7 | c.2660G>T p.S887I | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ZC3H12A | c.160T>C p.F54L | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ZC3H13 | c.2282A>T p.E761V | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZC3H4 | c.1625del p.P542Rfs*59 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel
- ZEB1 | c.2324dup p.E776Gfs*44 | Frame Shift Ins (INS) | VAF 90/271 reads (33%) | called by mutect2, pindel, varscan2
- ZG16 | c.106A>G p.K36E | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF131 | c.979del p.I327Ffs*45 (on ENST00000509156 / NM_001330707.2; = p.I293Ffs*45 on NM_003432.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 50/160 reads (31%) | called by mutect2, pindel, varscan2
- ZNF234 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ZNF267 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ZNF347 | c.142G>T p.G48* | Nonsense Mutation (SNP) | VAF 50/141 reads (35%) | called by muse, mutect2, varscan2
- ZNF506 | c.345del p.G116Afs*5 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- ZNF518A | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF565 | c.41A>T p.H14L | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated, low confidence (0.42); called by muse, mutect2, varscan2
- ZNF579 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF608 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF865 | c.2351del p.G784Vfs*25 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- ZSCAN29 | c.656A>T p.D219V | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ABCB7 | c.1923G>A p.S641= (on ENST00000373394 / NM_001271696.3; = p.S642= on NM_004299.6) | Silent (SNP) | VAF 56/182 reads (31%) | catalogued as rs774448307; called by muse, mutect2, varscan2
- ABCC1 | c.3399C>T p.Y1133= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as rs1011727501; called by muse, mutect2, varscan2
- ACACB | c.3984G>A p.P1328= | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as rs202082412; called by muse, mutect2, varscan2
- ACOT1 | c.178C>T p.L60= | Silent (SNP) | VAF 72/99 reads (73%) | called by muse, mutect2, varscan2
- ACTC1 | c.423G>A p.V141= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as rs922191208; ClinVar: likely benign; called by muse, mutect2, varscan2
- AHDC1 | c.2556C>T p.L852= | Silent (SNP) | VAF 37/325 reads (11%) | called by muse, mutect2, varscan2
- AHI1 | c.1593C>T p.Y531= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs370332260; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALPK1 | c.3486C>T p.G1162= | Silent (SNP) | VAF 64/225 reads (28%) | called by muse, mutect2, varscan2
- ANK3 | c.12153G>A p.T4051= | Silent (SNP) | VAF 55/154 reads (36%) | catalogued as rs1190946768, COSV55057983; called by muse, mutect2, varscan2
- APBA2 | c.1818T>G p.A606= | Silent (SNP) | VAF 62/236 reads (26%) | catalogued as rs1453567031; called by muse, varscan2
- ARHGEF28 | c.1578G>A p.P526= | Silent (SNP) | VAF 88/249 reads (35%) | catalogued as rs550141930; called by muse, mutect2, varscan2
- ASB2 | c.516C>T p.A172= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs764828472, COSV60111750; called by mutect2, varscan2
- ATAD2 | c.720C>T p.G240= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs1251902195; called by muse, mutect2, varscan2
- AUTS2 | c.960G>A p.P320= | Silent (SNP) | VAF 92/260 reads (35%) | catalogued as rs769492646; called by muse, mutect2, varscan2
- BCORL1 | c.1836C>T p.A612= | Silent (SNP) | VAF 70/209 reads (33%) | catalogued as rs1205598081; called by muse, mutect2, varscan2
344 further variants in this file (0 protein-altering or splice-affecting, 185 silent, 159 other) are not listed here.
